Gene-level copy-number profile of tumor specimen TCGA-50-5930-01A from TCGA case TCGA-50-5930, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.2 years (17,238 days).
Specimen TCGA-50-5930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2791d2ae-3139-47d6-99e8-94b4146cc0a9.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,973 have no estimate.
https://portal.gdc.cancer.gov/files/94a24124-a91b-42bd-a499-90d485df43c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 260; copy number 2: 51,270; copy number 3: 4,024; copy number 4: 96.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5930-01A-11D-1752-01): tumor purity 0.95, ploidy 2.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 260. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
